TCGA case TCGA-62-A46S — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Thoraxklinik at University Hospital Heidelberg. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e00a60d7-4253-443d-a187-680ad0931349

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 73 years; Vital status: Dead; Days to death: 1,653 days (4.5 years).

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 73.4 years (26,825 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial + Erlotinib Hydrochloride; Days to treatment start: 78 days; Days to treatment end: 198 days; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 74.9 years (27,352 days); Days to diagnosis: 527 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Day 527 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 527 days (1.4 years); Evidence of progression type: Convincing Image Source.
- Day 527 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 527 days (1.4 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,653 days (4.5 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 66; FEV1 before bronchodilator (% of reference): 72.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-62-A46S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-62-A46S-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-62-A46S-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-62-A46S-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Papillary Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Tarceva.
- Drug treatment 2: Pharmaceutical therapy drug name: Placebo.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,653 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,653 days; disease-free interval: event (new tumor event after initially disease-free), 527 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 527 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-62-A46S-01A-11D-A24C-01): tumor purity 0.45, ploidy 3.85, whole-genome doublings 1.
